TCGA case TCGA-UB-A7MC — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f82aff25-0725-48d1-aefd-d60800f7d1ab

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Alive.

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 59.5 years (21,733 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 1,2 - Portal Fibrosis.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin + Mitomycin; Days to treatment start: 343 days; Embolic agent: Lipiodol.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin + Mitomycin; Days to treatment start: 351 days; Embolic agent: Lipiodol.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin + Mitomycin; Days to treatment start: 371 days (1.0 years); Embolic agent: Lipiodol.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin + Mitomycin; Days to treatment start: 471 days (1.3 years); Embolic agent: Lipiodol.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Adrenal gland, NOS. Age at diagnosis: 60.5 years (22,092 days); Days to diagnosis: 359 days; Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 359 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence anatomic site: Adrenal gland, NOS; Days to recurrence: 359 days.
- Days to follow up: 500 days (1.4 years); Disease response: With Tumor.
- ECOG performance status: 0.
- Follow-up contact recording only the day: day 438.

Molecular and laboratory tests
- Albumin 3.9 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 4.8].
- Platelets 200 (unit not recorded by GDC) [Blood test normal range lower: 140; Blood test normal range upper: 450].
- Creatinine 0.7 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.2].
- Total Bilirubin 1.5 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.3].
- Alpha Fetoprotein 126 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 8].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 0.9 [Blood test normal range lower: 0.9; Blood test normal range upper: 1.2].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption / Hepatitis B Infection; Viral hepatitis serology tests: Hepatitis B Surface Antigen / HBV DNA / Hepatitis C Antibody.
- Timepoint category: Initial Diagnosis; Weight: 78 kg; Height: 176 cm; BMI: 25.2.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-UB-A7MC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 540 mg.
  Slide TCGA-UB-A7MC-01A-01-TSA: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-UB-A7MC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-UB-A7MC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy; Hepatic inflammation adj tissue: Mild.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: Hbv dna.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Ablations, Ablation 1, Ablation treatments: Ablation performed indicator: No.
- Ablations, Ablation 1, Embolization treatments: Embolization performed indicator: Yes.
- Ablations, Ablation 1, Embolization treatments, Embolization treatment 5: Embolization therapy drug name: Mitomycin C.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 500 days; disease-specific survival: no event (censored), 500 days; disease-free interval: event (new tumor event after initially disease-free), 359 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 359 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-UB-A7MC-01A-11D-A33P-01): tumor purity 0.9, ploidy 2.95, whole-genome doublings 1.
